TCGA case TCGA-CN-6024 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and unspecified parts of tongue; Tissue source site: University of Pittsburgh. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2fc48edb-a428-49c3-9599-d00eb2b448ac

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 66 years; Vital status: Dead; Days to death: 337 days.

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C02.9; Tissue or organ of origin: Tongue, NOS; Site of resection or biopsy: Head, face or neck, NOS; Classification of tumor: primary; Age at diagnosis: 66.4 years (24,259 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC clinical T: T4a; AJCC clinical N: N2; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N2c; AJCC pathologic M: M0; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Extranodal extension: Microscopic Extension; Lymph nodes positive: 6; Lymph nodes tested: 39; Lymphatic invasion present: Yes; Margin status: Uninvolved; Perineural invasion present: Yes; Vascular invasion present: Yes.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Rectum, NOS; Classification of tumor: Synchronous primary; AJCC staging edition: 7th.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 36 days; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin; Days to treatment start: 99 days; Treatment anatomic sites: Body, total.
3. Recurrence of diagnosis 1 (Squamous cell carcinoma, NOS), site: Lymph nodes of head, face and neck. Age at diagnosis: 66.8 years (24,415 days); Days to diagnosis: 156 days; Prior treatment: Yes.
   Recorded as not given: Surgery, NOS to Locoregional Site, for recurrent disease.

Follow-up (3 entries)
- Day 156 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph nodes of head, face and neck; Days to recurrence: 156 days.
- Days to follow up: 224 days; Disease response: With Tumor.
- Days to follow up: 337 days; Disease response: With Tumor.

Molecular and laboratory tests
- CDKN2A: Negative.
- Involved Tissue, NOS human papillomavirus (ISH): Negative.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 150; Tobacco smoking onset year: 1960.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CN-6024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-CN-6024-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
  Slide TCGA-CN-6024-01A-01-BS1: Section location: Bottom; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 20.
- Sample TCGA-CN-6024-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CN-6024-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Anatomic organ subdivision: Oral Tongue; Lymph nodes examined: Yes; Lymph nodes examined IHC count: 0; Lymph node neck dissection indicator: Yes; Lymphovascular invasion: Yes; Tobacco smoking history indicator: 2; Alcohol history documented: Yes.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event site: Cervical Lymph Nodes; Treatment outcome first course: Progressive Disease.
- Follow-up form 2: Tumor status: With tumor; Treatment outcome first course: Progressive Disease; Treatment outcome at TCGA followup: Progressive Disease.
- Other malignancy form: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Rectum; Other malignancy histological type: Rectal Adenocarcinoma.
- Other malignancy form, Drug treatment: Pharmaceutical therapy extent: Systemic.
- Other malignancy form, Drug treatment, Administered drug: Pharmaceutical therapy drug name: 5fu Leukovorin CPT-11.
- Other malignancy form, Radiation treatment: History radiation treatment to site of TCGA tumor: No.

GDC annotations on this case (curator notes; quoted as recorded):
- Synchronous malignancy: Pt with synchronous malignancy of the rectum.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 337 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 337 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 156 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CN-6024-01A-11D-1682-01): tumor purity 0.61, ploidy 2.99, whole-genome doublings 1.
